Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6093, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6093-01A (Primary Tumor).

[REDACTED]
[REDACTED]
[REDACTED] Surgical Pathology

[REDACTED] TCGA-CW-6093

TISSUE DESCRIPTION:

Right kidney (230 grams; 13.5 x 8.5 x 2.5 cm) with 8.5 cm of right ureter and gallbladder (9 x 3 x 1.5 cm)

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 1 (of 4) renal cell

carcinoma, clear cell type, forms a 2.5 x 2.5 x 2.5 cm mass located

in the mid kidney. The tumor is confined to the kidney. The renal

vein is grossly free of tumor. The tumor does not involve the

collecting system. Coagulative tumor necrosis is absent.

Sarcomatoid differentiation is absent. The surgical margins are

negative. No renal hilar lymph nodes are identified.

Gallbladder, cholecystectomy: Chronic cholecystitis with focal (0.5

cm) area of superficial ulceration in the fundus and cholelithiasis

(1 pigmented stone measuring 0.9 cm in diameter).

Source: NCI Genomic Data Commons file 4fb38b44-48a5-4791-b0c5-098a419af829 (TCGA-CW-6093.6616B396-4FB5-48A5-94F1-666DB94CAB51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).